TCGA case TCGA-CJ-4644 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8fd493c5-1375-4f76-b337-c9a75e3abdbe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 336 days.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.0 years (17,882 days); Year of diagnosis: 2004; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Vitespen; Initial disease status: Progressive Disease; Days to treatment start: 27 days; Days to treatment end: 229 days; Route of administration: Intramuscular.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 146 days; Days to treatment end: 146 days; Treatment dose: 2,000 cGy; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 150 days; Days to treatment end: 222 days; Prescribed dose: 2.5; Prescribed dose units: g/day; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon Alfa-2B; Initial disease status: Progressive Disease; Days to treatment start: 162 days; Days to treatment end: 222 days; Number of cycles: 1; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 194 days; Days to treatment end: 209 days; Treatment dose: 3,000 cGy; Course number: 2; Number of fractions: 12; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 229 days; Days to treatment end: 316 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 229 days; Days to treatment end: 316 days; Route of administration: Oral.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 49.2 years (17,975 days); Days to diagnosis: 93 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 105 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 105 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 93 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 93 days.
- Day 93 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 93 days.
- Days to follow up: 336 days; Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Platelets: Elevated.
- Leukocytes: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.8; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-CJ-4644-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-CJ-4644-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-CJ-4644-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-CJ-4644-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4644-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 0.8; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Oncophage; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IM.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: Tarceva; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Intron A; Therapy regimen: Progression.
- Drug treatment 4, Route of administrations: Route of administration: SC.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 336 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 336 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 93 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4644-01A-02D-1322-01): tumor purity 0.58, ploidy 2.07, whole-genome doublings 0.
